Surgical pathology report (de-identified scan), TCGA case TCGA-3P-A9WA, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Greenville Health System, specimen TCGA-3P-A9WA-01A (Primary Tumor).

[page 1 of 4]
PATHOLOGY EXAMINATION

COLLECTED:

CLIENT:

ADDITIONAL: NO ADDITIONAL PHYSICIANS
COPY TO/NOTES:

Page 1 of 4

SPECIMEN(S) RECEIVED:

A: Left tube and ovary
B: Uterus + cervix
C: Omentum
D: Sigmoid biopsy
E: Left pelvic side wall
F: Right tube and ovary
G: Left pelvic lymph node
H: Left common iliac lymph node
I: Right pelvic lymph node
J: Aortic lymph node
K: Right side wall biopsy

ACE *ICD-O-3*
path *Cystadenocarcinoma 8440/3*
Carcinoma, papillary serous 8260/3
Site: Ovary 156.9
8/27/14

CLINICAL DATA/HISTORY:

Not provided.

FINAL PATHOLOGIC DIAGNOSIS:

A, B, C, D, E, F, G, H, I, J, K. LEFT TUBE AND OVARY, UTERUS AND CERVIX, OMENTUM, SIGMOID BIOPSY, LEFT PELVIC SIDE WALL, RIGHT TUBE AND OVARY, LEFT PELVIC LYMPH NODE, LEFT COMMON ILIAC LYMPH NODE, RIGHT PELVIC LYMPH NODE, AORTIC LYMPH NODE, AND RIGHT SIDE WALL BIOPSY:

- LEFT OVARY WITH HIGH GRADE PAPILLARY SEROUS CARCINOMA.
- TUMOR SIZE: 7.5 X 5 X 5 CM.
- SPECIMEN RECEIVED DISRUPTED.
- LEFT PELVIC SIDE WALL BIOPSY POSITIVE FOR SEROUS CARCINOMA.
- REMAINING SPECIMENS NEGATIVE FOR ATYPICAL CHANGE OR MALIGNANCY.
- REGIONAL LYMPH NODES INCLUDING LEFT PELVIC NODE, LEFT COMMON ILIAC NODE, RIGHT PELVIC NODE, AND AORTIC LYMPH NODE NEGATIVE FOR METASTATIC CARCINOMA. SEE SYNOPSIS REPORTS BELOW.

SYNOPTIC REPORTS:

- SPECIMEN: RIGHT AND LEFT OVARIES, RIGHT AND LEFT FALLOPIAN TUBES, UTERUS, CERVIX, OMENTUM, LEFT PELVIC SIDE WALL AND RIGHT PELVIC SIDE WALL.
- PROCEDURE: HYSTERECTOMY AND BILATERAL SALPINGO-OOPHORECTOMIES WITH OMENTECTOMIES, LEFT AND RIGHT SIDE WALL AND SIGMOID BIOPSIES.
- LYMPH NODE SAMPLING: PERFORMED WITH LEFT PELVIC NODE, LEFT COMMON ILIAC NODE, RIGHT PELVIC NODE AND AORTIC NODE.
- SPECIMEN INTEGRITY: LEFT OVARY RECEIVED DISRUPTED.
- PRIMARY TUMOR SITE: LEFT OVARY.
- OVARIAN SURFACE INVOLVEMENT: ABSENT.
- TUMOR SIZE: 7.5 X 5 X 5 CM (GROSS MEASUREMENT).
- HISTOLOGIC TYPE: SEROUS CARCINOMA.
- HISTOLOGIC GRADE: POORLY DIFFERENTIATED/HIGH GRADE.
- EXTENT OF INVOLVEMENT OF OTHER ORGANS AND TISSUES:
- RIGHT OVARY NOT INVOLVED.
- RIGHT AND LEFT FALLOPIAN TUBES NOT INVOLVED.
- OMENTUM NOT INVOLVED.
- UTERUS NOT INVOLVED.

[page 2 of 4]
- o PERITONEUM INCLUDING LEFT PELVIC SIDE WALL AND RIGHT PELVIC SIDE WALL AND SIGMOID NOT INVOLVED.
- PRIOR ENDOMETRIAL POLYP SPECIMEN [REDACTED] INTRAEPITHELIAL SEROUS CARCINOMA.
- LYMPHOVASCULAR INVASION: NOT IDENTIFIED.
- PATHOLOGIC STAGE: pT2b pN0 (FIGO STAGE 2B).
- REGIONAL LYMPH NODES (SUMMARY OF G, H, I, J):
- o 3 OF 3 LEFT PELVIC LYMPH NODES (SPECIMEN G).
- o NO LEFT COMMON ILIAC LYMPH NODE PRESENT (SPECIMEN H).
- o 1 OF 1 RIGHT PELVIC LYMPH NODES (SPECIMEN I).
- o 1 OF 1 AORTIC LYMPH NODES (SPECIMEN J):
- o ALL NEGATIVE FOR METASTATIC CARCINOMA.
- ADDITIONAL PATHOLOGIC FINDINGS:

EXTENSIVELY SAMPLED ENDOMETRIUM NEGATIVE FOR RESIDUAL INTRAEPITHELIAL SEROUS CARCINOMA.

ADENOMATOID TUMOR AND MULTIPLE LEIOMYOMAS.

CHRONIC CERVICITIS WITH SQUAMOUS METAPLASIA.

NEGATIVE FOR ATYPICAL CHANGE OR MALIGNANCY.

BENIGN SEROSA AND FALLOPIAN TUBES.

UNREMARKABLE OMENTUM.

RIGHT SIDEWALL BIOPSY: CAUTERIZED FIBROADIPOSE TISSUE NEGATIVE FOR ATYPICAL CHANGE.

SIGMOID BIOPSY WITH GRANULATION TISSUE, MONONUCLEAR INFLAMMATION AND FIBROSIS.

NEGATIVE FOR ATYPICAL CHANGE OR MALIGNANCY. SEE COMMENT.

COMMENT:

See also [REDACTED] and [REDACTED]. No residual intraepithelial serous carcinoma is present within the extensively sampled endometrium. The ovary was received disrupted. Results discussed with [REDACTED]. These would appear to represent synchronous serous carcinomas of the ovary and endometrium.

ELECTRONICALLY SIGNED OUT

FROZEN SECTION DIAGNOSIS:

- A. LEFT TUBE AND OVARY: SEROUS CARCINOMA. Reported to [REDACTED]
- B. UTERUS AND CERVIX: NO TUMOR SEEN, LEIOMYOMA, ADENOMYOSIS AND POSSIBLE POLYP. Reported to [REDACTED]

GROSS DESCRIPTION:

A. Left tube and ovary: Received fresh labeled [REDACTED] "left tube and ovary" and consists of a 53 gram ovarian mass measuring 7.5 x 5 x 5 cm. The accompanying fimbriated fallopian tube measures 5 x 1 cm. Adjacent to the fallopian tube is a surface disruption measuring 1.5 cm. through which friable debris extends. The adjacent serosa is marked with black ink. The remaining ovarian surface is smooth and glistening to faintly bosselated. The ovary is serially sectioned revealing abundant friable tan cut surfaces. A representative portion of the specimen is frozen in A-FS1 cryoblock frozen section remnant as A1 with touch preparations x1 obtained. Three representative sections of the mass are utilized for tissue banking. Additional sections of the specimen are submitted for permanent section. A2) mass, two fragments adjacent to portion utilized for tissue banking. A3-A5) mass, two fragments per cassette. A6) fallopian tube.

B. Uterus + cervix: Received fresh for frozen section evaluation labeled [REDACTED] "uterus and cervix" and consists of a 99 gram uterus and cervix without adnexal complexes, measuring 10 x 7 x 4.5 cm. The asymmetric uterus has a faintly bosselated surface. The cervical epithellum is white, smooth and glistening with a slit-like cervical os measuring 0.9 cm in greatest dimension. The specimen is inked as follows: right parametrium green; left parametrium yellow; anterior uterus and cervix blue; posterior uterus and cervix black. The endocervical canal is patent and elliptical. The endometrium is tan with an average thickness of 0.2 cm. Sectioning of the myometrium reveals up to 3 well circumscribed, tan, whorled nodule with the largest measuring 2 cm in greatest dimension. The remaining myometrium is unremarkable and has an average thickness of 2.2 cm. Representative sections of the endometrium, myometrium and serosa along with a separate section of the largest tan nodule are frozen in B FS1

[page 3 of 4]
cryoblock with the FS remnant as B1 with touch preparations x 1 obtained. The gross dissection is directed by

No portion of the specimen is utilized for tissue banking due to the lack of grossly appreciated abnormality. Representative sections of the specimen are submitted for permanent section: B2) Right parametrium en face. B3) Left parametrium en face. B4) Anterior cervix. B5) Anterior lower uterine segment longitudinal (B4-B5 sections are contiguous, yellow ink designates adjacent tissue, not margin). B6) Posterior cervix. B7) Posterior lower uterine segment longitudinal (B6-B7 sections are contiguous, yellow ink designates adjacent tissue, not margin). B8) Anterior endometrium, myometrium, and serosa B9-B10) Anterior Endometrium B11) Posterior Endometrium, Myometrium, and Serosa, B12) Posterior Endometrium, B13-B14-B15) Whorled nodules

C. Omentum: Received in formalin labeled "Omentum", is a 24.8 x 7.7 x 2.0 cm portion of yellow, lobulated omentum. The specimen is serially sectioned to reveal yellow, lobulated, fatty cut surfaces. No discrete mass lesions or areas of nodularity are identified within the omentum.

Representative sections are submitted in C1-C5.

D. Sigmoid biopsy: Received in formalin labeled "Sigmoid biopsy", is a 1.3 x 1.0 x 0.3 cm irregular, pink-tan soft tissue which is placed into a filter bag and submitted in toto in D1.

E. Left pelvic side wall: Received in formalin labeled "Left pelvic side wall", is a 1.3 x 0.8 x 0.4 cm aggregate of three pink-tan soft tissues which are placed into a filter bag and submitted in toto in E1.

F. Right tube and ovary: Received in formalin labeled "Right tube and ovary", is a 14 gram adnexal complex which includes a 4.0 x 2.0 x 2.0 cm ovary with an attached 3.0 x 0.6 cm fimbriated fallopian tube. The outer surface of the ovary is pink-tan, smooth, displays a mild cerebriform architecture, and displays numerous simple cysts averaging 0.2-0.3 cm. Sectioning of the ovary reveals a pink-tan, smooth stroma. No ovarian mass lesions are identified. Sectioning of the fimbriated fallopian tube reveals a pinpoint and stellate lumen.

Representative sections are submitted as follows: F1 ovary. F2 fallopian tube to include fimbriae.

G. Left pelvic lymph node: Received in formalin labeled "Left pelvic lymph node", is a 3.5 x 2.0 x 0.6 cm irregular, yellow, lobulated portion of adipose tissue which contains three elongated, pink-yellow, fatty, ill-defined candidate lymph nodes ranging from 1.0 x 0.5 x 0.3 cm to 1.8 x 0.5 x 0.4 cm. The specimen is submitted in toto in G1.

H. Left common iliac lymph node: Received in formalin labeled "Left common iliac lymph node", is a 1.8 x 1.0 x 0.4 cm irregular, yellow, lobulated portion of adipose tissue with no easily palpable candidate lymph nodes. The specimen is submitted in toto in H1.

I. Right pelvic lymph node: Received in formalin labeled "Right pelvic lymph node", is a 1.8 x 0.6 x 0.5 cm elongated, fatty, tan-gray candidate lymph node which is bisected to reveal a fatty cut surface. The specimen is submitted in its entirety in I1.

J. Aortic lymph node: Received in formalin labeled "Aortic lymph node", is a 2.5 x 1.5 x 0.4 cm irregular, yellow, lobulated portion of adipose tissue which may contain a 0.5 x 0.3 x 0.3 cm somewhat palpable candidate lymph node. The specimen is submitted in toto in J1.

K. Right side wall biopsy: Received in formalin labeled "Right side wall biopsy", is a 1.6 x 1.0 x 0.5 cm irregular, purple-gray fibromembranous soft tissue which is submitted in toto in K1.

MICROSCOPIC DESCRIPTION:

A. Sections display papillary serous carcinoma. Permanent sections confirm the frozen section interpretation. No definitive surface involvement is present. Sections through the fimbriated end of the fallopian tube are negative.

B. Sections through the parametrium do not display any lymph nodes or atypical change. Sections through the cervix display a mononuclear inflammatory cell infiltrate with neutrophilic inflammation, squamous metaplasia and reactive epithelial changes. No dysplasia, HPV change or malignancy is present. Sections through the endometrium display basalis and proliferative phase endometrium. Sections through the myometrium display an adenomatoid tumor and multiple nodules of bland appearing spindle shaped smooth muscle cells. Areas of superficial adenomyosis are present. No residual intraepithelial serous carcinoma is present. No tumor is present within vascular spaces. The serosa does not display any endometriosis or atypical change. Sections through some of the leiomyomas display hyalinization and calcification.

C. Sections display omentum. No definitive metastatic carcinoma or endometriosis is present.

D. Sections display fibrous connective tissue with inflammation and reactive stromal changes. No definitive atypical change or malignancy is present. The specimen is entirely submitted for histologic evaluation.

E. Sections display serous carcinoma.

F. Sections display ovary with surface adhesions. No definitive atypical change or malignancy is present. Sections through the fallopian tube do not display any surface of fimbriated end involvement by serous carcinoma. No endometriosis is present.

G. Sections display three completely submitted lymph nodes. No metastatic carcinoma is present.

[page 4 of 4]
- H. The specimen is entirely submitted for histologic evaluation. No definitive nodal tissue or malignancy is present.
- I. Sections display completely submitted lymph node. No definitive metastatic carcinoma is present.
- J. Sections display lymph node. No metastatic carcinoma is present.
- K. Sections display fibroadipose connective tissue. No atypical change or malignancy is present.

UAPAA Discrepancy		/

Source: NCI Genomic Data Commons file f939d310-32ba-4170-84df-90443ec26da0 (TCGA-3P-A9WA.4B2E4D3D-128A-49DD-AE0B-ACFC78615B16.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).